Surgical pathology report (de-identified scan), TCGA case TCGA-L1-A7W4, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Hartford, specimen TCGA-L1-A7W4-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Adenocarcinoma, duct NOS
850013
Site Pancreas head
C25.0
JW 10/16/13

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

LOCATION:
SUBMITTING MD:
CC:

DIAGNOSIS

1. FALCIFORM LIGAMENT; EXCISION: BENIGN FIBROMUSCULAR AND ADIPOSE TISSUE; NEGATIVE FOR TUMOR.
2. GALLBLADDER; CHOLECYSTECTOMY: MILD CHRONIC CHOLECYSTITIS; NEGATIVE FOR TUMOR.
3. PANCREAS, STOMACH AND SMALL BOWEL; WHIPPLE PROCEDURE:

PANCREATIC DUCTAL ADENOCARCINOMA

Tumor site:	Head of pancreas
Tumor size:	2.8 cm
Histologic type:	Ductal Adenocarcinoma with focal non-keratinizing squamous component Per TSS, squamous totals 5%. BCR
Histologic grade:	Poorly differentiated
Microscopic tumor extension:	Tumor extends into the peripancreatic tissue and spares the ampulla
Margins:	Positive superior soft tissue margin; other pancreatic parenchymal margin, negative (see part 5) Negative bile duct margin Positive mesenteric vein margin (SMV) Negative mesenteric artery margin (SMA)
Treatment effect:	Not identified
Lymph-vascular invasion:	Identified
Perineural invasion:	Identified
Regional lymph nodes:	2/11 lymph nodes positive for metastatic carcinoma, with extranodal extension, largest focus measuring 1.7 cm (includes lymph node in specimen #5)
Distant metastasis:	Not identified
Other findings:	Chronic pancreatitis
pTNM:	pT3, pN1, pM0
AJCC (2010):	Stage IIB

4. PORTAL VEIN; RESECTION: POSITIVE FOR INVASIVE CARCINOMA.
5. PANCREAS; ADDITIONAL MARGIN; RESECTION: MARGIN NEGATIVE FOR INVASIVE CARCINOMA; ONE LYMPH NODE WITH METASTATIC DISEASE (1/1).
6. OMENTUM; OMENTECTOMY: BENIGN ADIPOSE TISSUE WITH A FOCAL FIBROTIC AND CALCIFIED NODULE; NEGATIVE FOR METASTATIC DISEASE.

Electronically Signed Out

[page 2 of 3]
COMMENT

Intraoperatively, the pancreatic margin shows crushed atypical cells (best seen on FS slides) and final pancreatic margin (slide 5A) is negative.

88331x2, 88332x2, 88309, 88304, 88305x4

Clinical Diagnosis and History:

Pancreatic ca

Tissue(s) Submitted:

- 1: FALCIFORM LIGAMENT
- 2: GALLBLADDER
- 3: WHIPPLE
- 4: PROTAL VEIN RESECTION
- 5: ADDITIONAL PANCREAS MARGIN
- 6: OMENTUM

Gross Description:

Specimen #1 is labeled with the patient name and falciform ligament. Received in formalin is a single piece of glistening piece of adipose tissue with a moderate amount of white fibrous tissue measuring 17.3 x 6.4 x 1.8 cm. The specimen is serially sectioned to reveal yellow, glistening adipose tissue with a single band of fibrous tissue.

1A-1B: two pieces each, muscle and ligament, representative

Specimen #2 is labeled with the patient name and gallbladder. Received in formalin is an intact gallbladder measuring 7.8 x 3.5 x 1 cm, with the cystic duct margin having a diameter of 0.4 cm. The serosa is tan-purple and smooth with no visible lesions or defects. The specimen is opened to reveal no luminal contents. The mucosa is red-pink and reticulated. No evidence of cholesterosis is appreciated. No choleliths are appreciated. The wall thickness measures 0.4 cm. Representative sections are submitted.

- 2A: cystic duct margin interrupting the sections of gallbladder
- 2B: multiple pieces, additional representative sections of gallbladder

Specimen #3 is received fresh in the frozen room labeled Whipple and consists of an intact Whipple specimen measuring 27.0 cm in length. The stomach measures 9.7 x 4.3 cm with the wall thickness of 0.7 cm. The duodenum measures 13 x 4.1 cm with a thickness of 0.4 cm. The pancreas measures 7.3 x 4.1 x 3.2 cm. The pancreas is sectioned to reveal a tumor mass measuring 2.8 x 1.9 x 1 cm. The tumor mass grossly approaches the SMV and anterior and superior margins. The tumor is grossly abutting the surgical margin. The tumor does not appear to be extending to the ampulla. The remaining pancreatic parenchyma is unremarkable. Inspection of the peripancreatic fat reveals three lymph nodes. The largest measuring 1.7 cm in greatest diameter and is grossly positive for tumor. The mucosa of the stomach of the stomach is tan-pink and unremarkable. The mucosa of the small bowel exhibits a sharp demarcation at the jejunum between viable and non-viable mucosa with non-viable mucosa being deep red and hemorrhagic and the viable being tan-brown with regular folds. The non-viable region extends approximately 7 cm from the distal margin. No gross masses, lesions or defects are appreciated on any of the mucosal surfaces. Inspection of the greater curvature adipose tissue reveals 10 presumptive lymph nodes. Representative sections are submitted. Summary of sections:

- 3A: one piece, frozen section of bile duct margin
- 3B: one piece, frozen section of pancreatic margin
- 3C: one piece, frozen section of deep bile duct
- 3D: two pieces, small bowel margin
- 3E: two pieces, stomach margin
- 3F: two pieces, non-viable small bowel
- 3G: two pieces, viable small bowel
- 3H: two pieces, stomach
- 3I-J: multiple pieces each, one lymph node from greater curvature
- 3K-L: multiple pieces, one lymph node from greater curvature
- 3M: four pieces, four presumptive lymph nodes
- 3N: four pieces, four presumptive lymph nodes
- 3O-P: one piece each, representative fat from greater curvature
- 3Q: one piece, ampulla
- 3R: anterior margin

[page 3 of 3]
Surgical Pathology Report

3S-T: one piece superior margin
3U: one piece SMV margin tumor
3V: one piece SMA margin
3W-Z: one piece each, representative sections of tumor
3AA-BB: one piece each, representative sections of the uninvolved pancreas with peripancreatic fat.
3CC-EE: multiple pieces each, one lymph node
3FF: multiple pieces, one lymph node
3GG: multiple pieces, one lymph node, representative and all lymph nodes entirely

Specimen #4 is labeled with the patient, portal vein resection. Received in formalin are two fragments of tan-pink tissue with the smaller measuring 0.3 x 0.2 x 0.2 cm and the larger measuring 0.7 x 0.6 x 0.4 cm. The specimen is submitted in entirety.

4A: multiple pieces, portal vein resection, all

Specimen #5 is received fresh labeled additional pancreas margin and consists of a single segment of pancreas measuring 2.6 x 1.5 x 0.8 cm in thickness. The distal most aspect has been submitted for frozen section. The specimen is entirely submitted labeled:

5A: one piece, frozen section remnant
5B: remaining pancreas, all

Specimen #6 is labeled with the patient name, omentum. Received in formalin is a segment of yellow, glistening adipose tissue measuring 36.8 x 14.6 x 1.3 cm. The surface of the omentum does not exhibit any gross nodularity. Sectioning of the omentum reveals a single focus of fat necrosis measuring 0.5 cm in greatest diameter. Summary of sections:

6A-B: one piece each, area of fat necrosis
6C-E: one piece each, representative sections of omentum, representative.

Intraoperative Consult Diagnosis

3A/FSDX: NEGATIVE.
3B/FSDX: PANCREATIC MARGIN WITH SOME RARE ATYPICAL CELLS CAN NOT EXCLUDE ADENOCARCINOMA
3C/FSDX: ADDITIONAL BILE DUCT NEGATIVE.
5A/FSDX: NO INVASIVE CARCINOMA CAN NOT EXCLUDE PanIN.

Source: NCI Genomic Data Commons file 8a846354-966b-47ca-9d3f-133937970d7c (TCGA-L1-A7W4.9F0AF874-3063-43F9-A3E7-DBD31337C741.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).